Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9J8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9J8-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: M Service: Received:
Reported:
Submitting Physician:
Pathologist:
Intraop. Pathologist:
Performing Physician:

CLINICAL HISTORY:
NONE GIVEN.

PREOPERATIVE DIAGNOSIS:
LEFT KIDNEY TUMOR. MICROSCOPIC HEMATURIA.

SPECIMEN TYPE(S):
A: 11TH RIB CROSS ONLY
B: POSTERIOR MEDIAL CYST WALL FS
C: LEFT RENAL MASS FS

FINAL DIAGNOSIS:
A. 11TH RIB:
Bone with hematopoietic marrow; no evidence of malignancy.
B. POSTERIOR MEDIAL CYST WALL:
Vascularized fibroadipose tissue with chronic inflammation and adjacent renal parenchyma. No evidence of malignancy.
C. LEFT KIDNEY, PARTIAL NEPHRECTOMY:
Renal cell carcinoma, papillary, type II. (see Key Pathologic Findings)
Pathologic stage: pT1b NX MX.

KEY PATHOLOGIC FINDINGS:
Tumor type: Renal cell carcinoma, papillary, type II.
Nuclear grade: III/IV
Pattern of growth: Unifocal and solid.
Tumor size: 4.3 cm.
Renal capsule invasion: Not identified.
Invasion of Gerota's Fascia: Not applicable.
Renal vein invasion: Not applicable.
Surgical margins: Free of malignancy.
Angiolymphatic invasion: Not identified.
Perineural invasion: Not identified.
Non-neoplastic kidney: Unremarkable.
Adrenal gland: Not applicable.
Lymph nodes: Not applicable.

ICD O.3
Carcinoma, papillary renal cell
Site: L4 Kidney NOS 8260/3
C64.9
W 4/28/14

I, the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically Signed out by

OTHER RELATED CLINICAL DATA:
NA

INTRAOPERATIVE DIAGNOSIS:
FSB1. POSTERIOR MEDIAL CYST WALL:
Fibrotic tissue with atypical cells; adjacent glomerulus and crushed tubules identified. Defer to permanent. Requested more tissue if applicable.

[page 2 of 2]
COMMENT: This frozen section diagnosis/result was communicated to and acknowledged by

FSCL. LEFT RENAL MASS:
Renal cell carcinoma. Margins free of tumor.

INTRADEPARTMENTAL CONSULTATION:

- C. GROSS EXAMINATION, LEFT RENAL MASS:
Grossly tumor is 0.5 cm from the renal parenchymal margin.
The closest negative surface margin is a thin fibrous capsule.

I, , have performed the intraoperative
consultation and issued the above diagnoses.

GROSS DESCRIPTION:

- A. The specimen is received fresh in 3 containers. Specimen A is labeled "left rib". The specimen consists of 2 unoriented fragments of rib which are ranging from 1.0 to 3.0 cm in length, with a small amount of adjacent tan, red-brown, soft to rubbery tissue. Both resection margins of fragments are grossly unremarkable. Tangential section of both resection margins submitted in 2 cassettes, A1 and A2, following decalcification.
- B. Specimen B is labeled "posterior medial cyst wall". The specimen consists of an irregular, unoriented fragment of tan, red-brown rubbery tissue measuring 0.6 x 0.2 x 0.1 cm, which is submitted entirely for frozen section as FS2.
- C. Specimen C is labeled "left renal mass frozen section for diagnosis and margin, check deep margin plus ink margin plus inked surface margin". The specimen consists of a partial nephrectomy specimen which is measuring 5.5 x 5.0 x 4.5 cm with a moderate amount of adjacent to capsule perinephric adipose tissue which is ranging from 0.1 to 0.9 cm in thickness. The parenchymal resection margin is tan, red-brown, grossly unremarkable. The specimen is oriented according to the surgeon's designation and inked as follows:
Parenchymal resection margin Black
Perinephric adipose tissue
resection margin Blue.

The specimen is serially sectioned to reveal an irregular to ovoid, ill-defined tumor which is measuring 4.2 x 4.1 x 4.0 cm. The tumor is bulging, but does not appear to extend through the renal capsule and within 0.1 cm of the resection margin of the perinephric adipose tissue. The tumor grossly 0.5 cm of the parenchymal resection margin. The cut surface of the tumor is variegated, tan-pink to tan-red, focally necrotic and hemorrhagic. Representative section of the tumor with closest inked black parenchymal resection margin submitted for frozen section as FS2. Representative sections of the specimen submitted to the Tissue Procurement Laboratory. Representative sections of the specimen submitted in 7 cassettes as follows:

- C1-C2: Additional sections of the tumor with adjacent renal parenchyma
C3-C4: Central part of the tumor
C5-C7: Tumor bulging capsule.

Source: NCI Genomic Data Commons file 5ff43ee2-e0e4-4102-8760-26b6642a5153 (TCGA-2Z-A9J8.625DE530-9DB9-49BD-BA62-A161814A4658.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).